Somatic mutation profile of tumor specimen TCGA-04-1649-01A (aliquot TCGA-04-1649-01A-01W-0639-09) from TCGA case TCGA-04-1649, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.4 years (27,165 days).
Specimen TCGA-04-1649-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb718945-0cce-437c-a03d-f5d379ea2b9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1649-11A (Solid Tissue Normal), aliquot TCGA-04-1649-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/136cbbd5-492a-48c0-a9d2-6d97955299f8

The open-access MAF lists 86 somatic variants for this specimen: 67 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 2, Splice Site 1, 5'UTR 1, RNA 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.809T>C p.F270S | Missense Mutation (SNP) | VAF 105/159 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519986, COSV52661272, COSV52676663, COSV52688116; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACR | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs1334636659; called by muse, mutect2, varscan2
- ANKRD44 | c.236A>G p.H79R | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99984455; called by muse, mutect2, varscan2
- ATAD2B | c.4199G>C p.R1400T | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53201364; called by muse, mutect2, varscan2
- C1orf116 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 25/344 reads (7%) | catalogued as COSV100847898; called by muse, mutect2
- C1orf131 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV59642562, COSV59643032; called by muse, mutect2, varscan2
- CALCRL | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs773778926, COSV66474981, COSV66475097; called by muse, mutect2, varscan2
- CDH26 | c.1203C>A p.F401L | Missense Mutation (SNP) | VAF 16/552 reads (3%) | SIFT tolerated (0.83); PolyPhen benign (0.039); catalogued as COSV99722026; called by muse, mutect2
- CDK11A | c.357C>G p.H119Q (on ENST00000378633 / NM_001313896.2; = p.H129Q on NM_024011.4) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.907); catalogued as rs754630865, COSV100651654, COSV62266209; called by muse, mutect2
- CLCA4 | c.2432A>G p.N811S | Missense Mutation (SNP) | VAF 82/429 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV65284000; called by muse, mutect2, varscan2
- COL5A2 | c.4070A>G p.N1357S | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs1163698455, COSV66411107; called by muse, mutect2, varscan2
- CRISP3 | c.383G>A p.G128D (on ENST00000371159 / NM_001368123.1; = p.G110D on NM_006061.4) | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99538757; called by muse, mutect2
- CSH2 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs760428919, COSV61080643; called by muse, mutect2, varscan2
- CXCR3 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | catalogued as COSV65462064; called by muse, mutect2, varscan2
- CYP2D6 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs201501394; called by muse, mutect2, varscan2
- DAB1 | c.433C>A p.Q145K | Missense Mutation (SNP) | VAF 20/610 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV59732802; called by muse, mutect2
- DCC | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 132/441 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100501855, COSV59091972; called by muse, mutect2, varscan2
- DSCAM | c.4022A>G p.N1341S | Missense Mutation (SNP) | VAF 88/368 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV68029745; called by muse, mutect2, varscan2
- EHD3 | c.818C>A p.A273D | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV100434653; called by muse, mutect2
- ENPP2 | c.75C>A p.C25* | Nonsense Mutation (SNP) | VAF 24/434 reads (6%) | catalogued as COSV99307833; called by muse, mutect2
- ENPP4 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 12/387 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320263, COSV58088784; called by muse, mutect2
- GPR101 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 44/804 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99981310; called by muse, mutect2
- GRAMD4 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.736); catalogued as COSV63030992; called by muse, mutect2, varscan2
- IFI44L | c.498C>G p.D166E | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as COSV60726830, COSV60728187; called by muse, mutect2, varscan2
- IGKV1D-33 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as rs1316506265; called by muse, mutect2, varscan2
- ITGB6 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 19/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324277; called by muse, mutect2
- KRTDAP | c.8T>A p.I3N | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as COSV58865421; called by muse, mutect2, varscan2
- LMNTD1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 216/381 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV51448254; called by muse, mutect2, varscan2
- MED24 | c.1155C>A p.R385= | Splice Region (SNP) | VAF 29/207 reads (14%) | catalogued as rs1446442944, COSV62419412; called by muse, mutect2, varscan2
- MIA3 | c.4378-1G>C p.X1460_splice | Splice Site (SNP) | VAF 109/610 reads (18%) | catalogued as COSV60514458; called by muse, mutect2, varscan2
- MSI1 | c.345dup p.L116Afs*15 | Frame Shift Ins (INS) | VAF 30/280 reads (11%) | catalogued as rs748469666; called by mutect2, varscan2
- MYO16 | c.141G>C p.R47S | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV51802058; called by muse, mutect2, varscan2
- NECAB1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1422398178, COSV70241206, COSV70242363; called by muse, mutect2, varscan2
- NETO1 | c.1013T>G p.L338R | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); catalogued as COSV55009160; called by muse, mutect2, varscan2
- NFYC | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58127978; called by muse, mutect2, varscan2
- NR4A2 | c.325dup p.Q109Pfs*3 | Frame Shift Ins (INS) | VAF 14/120 reads (12%) | catalogued as rs774629025; called by mutect2, varscan2
- OTOL1 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs1278113905, COSV60007249; called by muse, mutect2, varscan2
- PNLDC1 | c.1249A>T p.S417C | Missense Mutation (SNP) | VAF 105/130 reads (81%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51706218; called by muse, mutect2, varscan2
- PPP2R2A | c.229T>C p.F77L | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV60097836; called by muse, mutect2, varscan2
- PUM3 | c.71A>T p.H24L | Missense Mutation (SNP) | VAF 97/406 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs772434075, COSV67396716; called by muse, mutect2, varscan2
- RIMBP2 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752922218, COSV55476511; called by muse, mutect2, varscan2
- RPTOR | c.3817G>A p.V1273I | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs771184410, COSV60803963; called by muse, varscan2
- SALL3 | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as rs778334113, COSV73306140; called by muse, mutect2, varscan2
- SLC36A2 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58863851; called by muse, mutect2, varscan2
- SLC6A4 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751233939, COSV55564744; called by muse, mutect2, varscan2
- SMOC2 | c.593C>A p.T198N (on ENST00000356284 / NM_001166412.2; = p.T209N on NM_022138.3) | Missense Mutation (SNP) | VAF 77/307 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV62433986; called by muse, mutect2, varscan2
- SPAG17 | c.3776G>A p.R1259H | Missense Mutation (SNP) | VAF 34/455 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202113364; called by muse, mutect2
- SPRY1 | c.578C>A p.T193N | Missense Mutation (SNP) | VAF 140/603 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59338666; called by muse, varscan2
- STRC | c.3533C>A p.T1178N | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.506); catalogued as COSV68660001; called by muse, mutect2, varscan2
- SYNE1 | c.3494G>A p.R1165H (on ENST00000367255 / NM_182961.4; = p.R1172H on NM_033071.3) | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs201354687, COSV55020463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAAR6 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV51583425, COSV99256846; called by muse, mutect2
- TARDBP | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV53570344; called by muse, mutect2, varscan2
- TCAF1 | c.2485G>A p.A829T | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172751375, COSV63518322; called by mutect2, varscan2
- TDRD1 | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs866270956, COSV52590715; called by muse, mutect2, varscan2
- TLK2 | c.1612G>T p.D538Y (on ENST00000326270 / NM_001284333.2; = p.D516Y on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100408866; called by muse, mutect2
- TNKS | c.415T>A p.S139T | Missense Mutation (SNP) | VAF 76/1715 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); catalogued as COSV100126457; called by muse, mutect2
- TNKS | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 76/1719 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs772995748, COSV60066288; called by muse, mutect2
- TSSK6 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV53064159, COSV53065231; called by muse, mutect2, varscan2
- VPS33B | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs747451890, COSV60980698; called by muse, mutect2, varscan2
- XIRP2 | c.4580C>A p.T1527K (on ENST00000628543; = p.T1702K on NM_152381.6) | Missense Mutation (SNP) | VAF 139/629 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV54711402; called by muse, mutect2, varscan2
- ZNF236 | c.1383G>A p.M461I | Missense Mutation (SNP) | VAF 36/495 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99469618; called by muse, mutect2
- ZNF536 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 8/246 reads (3%) | catalogued as COSV62820152; called by muse, mutect2
- BRS3 | c.699_711del p.S234Pfs*2 | Frame Shift Del (DEL) | VAF 37/216 reads (17%) | called by mutect2, pindel, varscan2
- CHD7 | c.8578dup p.S2860Kfs*9 | Frame Shift Ins (INS) | VAF 40/152 reads (26%) | called by mutect2, pindel, varscan2
- MUC5B | c.8060C>G p.P2687R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PDE4DIP | c.1254del p.R419Vfs*21 | Frame Shift Del (DEL) | VAF 144/1002 reads (14%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2848G>T p.V950L | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.669); called by muse, mutect2
- ADAMTS9 | c.870C>G p.S290= | Silent (SNP) | VAF 123/538 reads (23%) | catalogued as rs950461771, COSV55784176; called by muse, mutect2, varscan2
- C2CD5 | c.1854A>C p.I618= | Silent (SNP) | VAF 50/184 reads (27%) | catalogued as COSV61725454; called by muse, mutect2, varscan2
- CTDSP1 | c.744C>T p.D248= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as rs575930072, COSV56090247; called by muse, mutect2, varscan2
- DNAH9 | c.6366G>T p.L2122= | Silent (SNP) | VAF 78/156 reads (50%) | catalogued as COSV52357516; called by muse, mutect2, varscan2
- FRMPD3 | c.1179T>A p.P393= | Silent (SNP) | VAF 35/181 reads (19%) | catalogued as COSV52192911; called by muse, mutect2, varscan2
- KCNA6 | c.1455T>A p.P485= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as COSV54976146; called by muse, mutect2, varscan2
- NETO1 | c.708G>T p.V236= | Silent (SNP) | VAF 121/418 reads (29%) | catalogued as COSV55009171; called by muse, mutect2, varscan2
- NRXN1 | c.399G>T p.V133= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV101277109; called by muse, mutect2
- POM121L12 | c.426G>A p.A142= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV68692379; called by mutect2, varscan2
- PPP1R21 | c.1650C>T p.I550= | Silent (SNP) | VAF 79/275 reads (29%) | catalogued as COSV54286020; called by muse, mutect2, varscan2
- PTPRN2 | c.2466G>A p.P822= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs756403590, COSV67045606; called by muse, mutect2, varscan2
- RRNAD1 | c.663C>T p.S221= | Silent (SNP) | VAF 24/395 reads (6%) | catalogued as COSV100836900; called by muse, mutect2
- SERPINB3 | c.465G>T p.T155= | Silent (SNP) | VAF 28/151 reads (19%) | catalogued as COSV52192405, COSV52193246; called by muse, mutect2, varscan2
- SNX29 | c.516C>A p.L172= | Silent (SNP) | VAF 8/237 reads (3%) | catalogued as COSV60061005; called by muse, mutect2
- TIRAP | c.597C>A p.G199= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV101201569; called by muse, mutect2
- ZNF280B | c.441A>G p.T147= | Silent (SNP) | VAF 281/668 reads (42%) | catalogued as COSV64529137; called by muse, mutect2, varscan2
- DOK3 | c.-97G>A | 5'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs755256832, COSV57253022; called by muse, mutect2, varscan2
- MAGED1 | c.45+321C>A | Intron (SNP) | VAF 26/129 reads (20%) | catalogued as COSV58515765, COSV58516837; called by muse, mutect2, varscan2
- UBTFL2 | n.931A>C | RNA (SNP) | VAF 7/50 reads (14%) | catalogued as rs1565434479; called by mutect2, varscan2
